Surgical pathology report (de-identified scan), TCGA case TCGA-F1-6874, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site UNC, specimen TCGA-F1-6874-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REVISED REPORT

Case Number : [REDACTED]

Diagnosis:

A: Stomach, subtotal gastrectomy

Histologic tumor type/subtype: moderately to poorly differentiated
adenocarcinoma, intestinal type

Histologic grade: moderately to poorly differentiated

Tumor location: proximal stomach

Depth of invasion: into muscularis propria

Lymphovascular invasion: not identified

Perineural invasion: not identified

Histologic assessment of surgical margins:

Proximal surgical margin: negative for malignancy; tumor is 1.9 cm from the proximal margin; see comment

Distal surgical margin: negative for malignancy; margin is widely negative

Radial (adventitial) margin: negative for malignancy, tumor is 0.4 cm from the radial margin

Lymph nodes: 32 lymph nodes, negative for malignancy (0/32)

Other significant findings:

- Chronic gastritis with extensive intestinal metaplasia.
- No *Helicobacter pylori* identified.
- Acute and chronic serositis.
- Hyperplastic polyp.

AJCC Staging: pT2 pN0

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

[page 2 of 5]
B: Greater omentum #1, partial omentectomy
- Mature benign fibroadipose tissue consistent with omentum
- No carcinoma identified

C: Greater omentum #2, partial omentectomy
- Mature benign fibroadipose tissue consistent with omentum
- No carcinoma identified

D: Greater omentum #3, partial omentectomy
- Mature benign fibroadipose tissue consistent with omentum
- No carcinoma identified

E: Greater omentum #4, partial omentectomy
- Mature benign fibroadipose tissue consistent with omentum
- No carcinoma identified

F: Greater omentum #5, partial omentectomy
- Mature benign fibroadipose tissue consistent with omentum
- No carcinoma identified

G: Lymph node, celiac, hepatic, removal
- Six lymph nodes, negative for malignancy (0/6)

Comment:

Gross examination estimates the tumor mass to be 3 cm from the proximal margin.

Microscopic examination demonstrates no tumor at the proximal margin with a microscopic distance of 1.9 cm between tumor and the proximal margin.

This case was reviewed with the frozen section pathologist [REDACTED] regarding proximal margin status.

Intraoperative Consult Diagnosis:

A frozen section was requested by [REDACTED] [REDACTED]

FSA1: Distal margin, gastrectomy
- No tumor seen

FSA2: Proximal margin, gastrectomy
- No tumor seen at margin, approximately 3 cm

[REDACTED]

[page 3 of 5]
[REDACTED]
[REDACTED]:

[REDACTED] with biopsy proven poorly differentiated
cinoma.

Gross Description:

Received are seven appropriately labeled containers.

Container A is additionally labeled "subtotal gastrectomy with perigastric lymph node, stitch marks greater curve." The specimen is a 20 x 16 x 3.5 cm overall gastrectomy specimen composed of a 20.0 x 4.5 x 3.5 cm stomach with attached greater and lesser omentum. The specimen is received oriented with a stitch along the proximal margin greater curvature. The anterior serosa is predominantly smooth, tan/pink with a 0.4 cm solitary soft fluctuant nodule. The posterior serosa is smooth, tan/pink and unremarkable. Both margins have been received stapled and the proximal margin staple line is inked blue and the distal staple line is inked black. The specimen is opened along the greater curvature. Opening demonstrates a 5.5 x 5.0 x 2.5 cm fleshy broad-based polypoid mass extending into the muscularis propria and within 0.1 cm of the underlying posterior serosa which is grossly intact. This mass is covered with granular and discolored necrotic appearing mucosa. The mass is located 3 cm from the proximal staple line. The proximal and distal margins are frozen as FSA1 and FSA2. The remaining gastric mucosa is brown/red, granular with prominent rugal folds and some flattening adjacent to the polyp. There is a second 0.6 x 0.5 x 0.4 cm polyp located 10 cm distal to the first mass. Sectioning through the mass reveals a fleshy, yellow/tan cut surface.

Normal and tumor have been given to Tissue Procurement.

[page 4 of 5]
Block summary:

FSA1 - distal margin

FSA1 - proximal margin

A1 - anterior wall serosal nodule

A2-A3 - full thickness sections of tumor to include serosa

A4 - proximal edge of tumor

A5 - distal edge of tumor

A6 - superficial section of tumor

A7 - polyp, distal

A8 - representative sections from erythematous and slightly flattened

gastric mucosa

A9 - five lymph node candidates, lesser curvature

A10 - five lymph node candidates, lesser curvature

A11 - three lymph node candidates, lesser curvature

A12-A13 - one lymph node candidate, sectioned, lesser curvature

A14 - five lymph node candidates, greater curvature

A15 - five lymph node candidates, greater curvature

A16 - six lymph node candidates, greater curvature

A17 - five lymph node candidates

A18 - two lymph node candidates

Container B is additionally labeled "greater omentum #1." It holds a 14.8 x 9.2

x 2.3 cm fragment of finely lobulated yellow/tan fibrofatty tissue with focal

cautery artifact and areas of hemorrhage. The surfaces are smooth and

glistening. Sectioning reveals lobulated yellow/tan cut surfaces with no nodules

or masses appreciated. Representative sections are submitted in blocks B1-B3.

Container C is additionally labeled "greater omentum #2." It holds a 16.4 x 13.3

x 2.4 cm fragment of finely lobulated yellow/tan fibrofatty tissue with

predominantly smooth glistening surfaces. There is focal cautery artifact and

small areas of hemorrhage. No discrete mass or nodule is appreciated upon

sectioning. Representative sections are submitted in blocks C1-C3.

Container D is additionally labeled "greater omentum #3." It holds a 15.4 x 10.2

[page 5 of 5]
x 2.4 cm lobulated fragment of yellow/tan fibrofatty tissue with a predominantly glistening surface. There are small areas of hemorrhage and minimal cautery. Sectioning reveals lobulated, grossly unremarkable fatty cut surfaces with no discrete mass or nodule appreciated. Representative sections are submitted in blocks D1-D3.

Container E is additionally labeled "greater omentum #4." It holds a 21 x 12.5 x 2.2 cm lobulated fragment of yellow/tan fibrofatty tissue. The surfaces are predominantly smooth and glistening with small areas of hemorrhage. Sectioning reveals lobulated yellow/tan fatty cut surfaces with no discrete mass or nodule appreciated. Representative sections are submitted in blocks E1-E3.

Container F is additionally labeled "greater omentum #5." It holds a 15.3 x 12.8 x 2.4 cm lobulated fragment of yellow/tan fibrofatty tissue consistent with omentum. The surface is predominantly smooth and glistening with small areas of erythema. Sectioning reveals lobulated yellow/tan fatty cut surfaces with no discrete lesions identified. Representative sections are submitted in blocks F1-F3.

Container G is additionally labeled "celiac and common hepatic lymph nodes." It holds a 4.5 x 3.3 x 1.2 cm aggregate of cauterized yellow/tan fibrofatty tissue which is dissected for lymph node candidates. Four lymph node candidates measuring up to 1.4 cm in greatest dimension are identified.

Block summary:

G1 - three lymph node candidates
G2 - one lymph node candid
G3-G5 - remainder of fat,

Source: NCI Genomic Data Commons file c08fbc1c-6694-4869-bcb1-3eb615528407 (TCGA-F1-6874.E35B2A11-041E-4E6D-85E6-C04D759C30A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).